TCGA case TCGA-A6-6141 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/58facedb-fcb8-4ecf-8338-2bfa4947acef

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 31 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 31.2 years (11,391 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 255 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 19; Lymphatic invasion present: No; Non nodal tumor deposits: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 60 days; Days to treatment end: 214 days; Number of cycles: 12; Treatment dose: 10,200 mg; Prescribed dose: 850; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 60 days; Days to treatment end: 216 days; Number of cycles: 12; Treatment dose: 61,800 mg; Prescribed dose: 5150; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 60 days; Days to treatment end: 214 days; Number of cycles: 12; Treatment dose: 4,900 mg; Prescribed dose: 550; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 60 days; Days to treatment end: 214 days; Number of cycles: 12; Treatment dose: 2,160 mg; Prescribed dose: 180; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 130 days; Disease response: Tumor Free.
- Days to follow up: 255 days; Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 5 ng/mL.
- MLH1 (IHC): Normal.
- MSH2 (IHC): Normal.
- MSH6 (IHC): Normal.
- PMS2 (IHC): Normal.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 96.8 kg; Height: 177.8 cm; BMI: 30.6.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A6-6141-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.7; Shortest dimension: 0.6.
  Slide TCGA-A6-6141-01A-01-TS1: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
  Slide TCGA-A6-6141-01A-01-BS1: Section location: Bottom; Percent tumor cells: 99; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 10.
- Sample TCGA-A6-6141-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A6-6141-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Cecum; Lymph nodes examined: Yes; CEA level pretreatment: 5.0; Lymphovascular invasion indicator: No; Microsatellite instability: No; Loci tested count: 5; Loci abnormal count: 0; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Mismatch rep proteins tested by IHC: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Expressed; Mismatch rep proteins loss IHC: MSH2-Expressed; Mismatch rep proteins loss IHC: PMS2-Expressed; Mismatch rep proteins loss IHC: MSH6-Expressed.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: 5FU.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 255 days; disease-specific survival: no event (censored), 255 days; progression-free interval: no event (censored), 255 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A6-6141-01A-11D-1770-01): tumor purity 0.48, ploidy 2, whole-genome doublings 0.
